Somatic mutation profile of cancer-model specimen HCM-BROD-0595-C43-85M (Adherent Cell Line, passage 8; aliquot HCM-BROD-0595-C43-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0595-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage 0; Age at diagnosis: 47.2 years (17,247 days).
Specimen HCM-BROD-0595-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2262ce6a-e8dc-4732-9578-82319bf47575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0595-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0595-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb715ce9-18f4-4c17-80fd-5c5b610bc0cc

The open-access MAF lists 131 somatic variants for this specimen: 93 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 35, Splice Region 6, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, 3'UTR 1, Splice Site 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/303 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT11 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 137/416 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs139052769; called by muse, mutect2, varscan2
- ADAMTS18 | c.3337C>T p.R1113W | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs148910905; called by muse, mutect2, varscan2
- AGXT | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56753854; called by muse, mutect2, varscan2
- ANKK1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 161/338 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58274862; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 325/325 reads (100%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- CD163 | c.1736-8C>T | Splice Region (SNP) | VAF 149/461 reads (32%) | catalogued as COSV63129888; called by muse, mutect2, varscan2
- CNNM1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1044720732; called by muse, mutect2, varscan2
- COL28A1 | c.927+1G>A p.X309_splice | Splice Site (SNP) | VAF 126/265 reads (48%) | catalogued as rs370508064; called by muse, mutect2, varscan2
- CRB1 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 252/587 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66328793; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DNAH17 | c.10135G>A p.E3379K | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as rs865785284; called by muse, mutect2, varscan2
- EPHA3 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs200415022, COSV60720631; called by muse, mutect2, varscan2
- GRIA1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53598315; called by muse, mutect2, varscan2
- GRIN2B | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761084398; called by muse, mutect2, varscan2
- IGSF5 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 225/437 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs780927418; called by muse, mutect2, varscan2
- IL36A | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52083544; called by muse, mutect2, varscan2
- IQCH | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 86/442 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as COSV60058629; called by muse, mutect2, varscan2
- KIF1B | c.3262T>G p.L1088V (on ENST00000377086 / NM_001365952.1; = p.L1042V on NM_015074.3) | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as rs1001609597, COSV55818712; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 373/753 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, mutect2, varscan2
- KLF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 254/377 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53436163; called by muse, mutect2, varscan2
- LRRC3B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 144/419 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101185673; called by muse, mutect2, varscan2
- LYPD4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs1555831271; called by muse, mutect2, varscan2
- MAGED1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782402643, COSV58516219; called by muse, mutect2, varscan2
- NFIA | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 308/311 reads (99%) | SIFT tolerated, low confidence (0.91); catalogued as rs1218189561; called by muse, mutect2, varscan2
- OPA1 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs766257852; called by muse, mutect2, varscan2
- OR52A1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61093497; called by muse, mutect2, varscan2
- ORC5 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs267601218, COSV99857320; called by muse, mutect2, varscan2
- PKHD1 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 323/552 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV61860281; called by muse, mutect2, varscan2
- PPARGC1A | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs762893416, COSV53525023; called by muse, mutect2, varscan2
- PWWP3B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 140/676 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61798632; called by muse, mutect2, varscan2
- SNCAIP | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs143440334; called by muse, mutect2, varscan2
- SNTG1 | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs779227339; called by muse, mutect2, varscan2
- SPNS3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs139407503; called by muse, mutect2, varscan2
- SVEP1 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57029299; called by muse, mutect2, varscan2
- SYT16 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1409503101, COSV70859455; called by muse, mutect2, varscan2
- TONSL | c.2806C>T p.R936* | Nonsense Mutation (SNP) | VAF 103/448 reads (23%) | catalogued as rs1156410886, COSV68048801; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 241/507 reads (48%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1440851175, COSV62507013, COSV62510751; called by muse, mutect2, varscan2
- VPS16 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558893855, COSV66792589; called by muse, mutect2, varscan2
- VSTM4 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs187843947; called by muse, mutect2, varscan2
- ZFHX4 | c.9616G>A p.E3206K | Missense Mutation (SNP) | VAF 110/467 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV99268039; called by muse, mutect2, varscan2
- ZNF831 | c.3322G>T p.G1108W | Missense Mutation (SNP) | VAF 421/845 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV64038804; called by muse, mutect2, varscan2
- ZNF99 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 192/335 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs970147679, COSV68054917; called by muse, mutect2, varscan2
- ADAMTS20 | c.5274_5300del p.Q1759_V1767del | In Frame Del (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- AEBP2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ALS2 | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 317/318 reads (100%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2B | c.3523G>A p.D1175N | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- C4orf50 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1B | c.6431C>T p.S2144F | Missense Mutation (SNP) | VAF 404/869 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CASS4 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 183/376 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CCNF | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 312/582 reads (54%) | called by muse, mutect2, varscan2
- CEP170 | c.2852A>G p.K951R | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL14A1 | c.4605G>A p.Q1535= | Splice Region (SNP) | VAF 81/378 reads (21%) | called by muse, mutect2, varscan2
- COL26A1 | c.287G>A p.R96K (on ENST00000313669 / NM_001278563.3; = p.X94_splice on NM_133457.4) | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- DYNLRB2 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 200/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EPHA10 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 439/439 reads (100%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABBR1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 304/1036 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT1 | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 126/201 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6A | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 98/603 reads (16%) | called by muse, mutect2, varscan2
- GOLGB1 | c.6130G>C p.A2044P | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2BC1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.1740C>T p.L580= | Splice Region (SNP) | VAF 133/253 reads (53%) | called by muse, mutect2, varscan2
- HOXC5 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 479/482 reads (99%) | SIFT tolerated (0.57); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- INPPL1 | c.958_967del p.L320* | Frame Shift Del (DEL) | VAF 187/194 reads (96%) | called by mutect2, pindel, varscan2
- MDFIC | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 107/209 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MEAF6 | c.91-8T>C | Splice Region (SNP) | VAF 121/414 reads (29%) | called by muse, mutect2, varscan2
- MXRA5 | c.6920G>A p.G2307E | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH6 | c.4959G>A p.K1653= | Splice Region (SNP) | VAF 346/346 reads (100%) | called by muse, mutect2, varscan2
- MZF1 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 168/750 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, varscan2
- NEDD4L | c.1824A>T p.L608F (on ENST00000400345 / NM_001144967.3; = p.L588F on NM_015277.6) | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NLRP7 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 208/453 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRCAM | c.1237G>A p.D413N (on ENST00000379028 / NM_001371124.1; = p.D407N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2
- NRK | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OBSCN | c.12085G>C p.D4029H | Missense Mutation (SNP) | VAF 134/664 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- OR5D3P | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PDZRN4 | c.2276C>T p.S759F (on ENST00000402685 / NM_001164595.2; = p.S501F on NM_013377.4) | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHN1 | c.982G>A p.E328K (on ENST00000379409; = p.E276K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 447/449 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PZP | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- QDPR | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SCN11A | c.178A>G p.R60G | Missense Mutation (SNP) | VAF 249/408 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SLCO1A2 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMAD4 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF9B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 525/663 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- TENM1 | c.5932C>T p.L1978F | Missense Mutation (SNP) | VAF 504/665 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEFF2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 247/249 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TOR1AIP2 | c.211_212del p.E71Kfs*4 | Frame Shift Del (DEL) | VAF 101/405 reads (25%) | called by mutect2, pindel, varscan2
- UIMC1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- VPS35L | c.2529G>A p.V843= | Splice Region (SNP) | VAF 54/210 reads (26%) | called by muse, mutect2, varscan2
- VWDE | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 204/468 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- WIZ | c.4021C>T p.P1341S (on ENST00000673675 / NM_001371589.1; = p.P246S on NM_021241.3) | Missense Mutation (SNP) | VAF 301/474 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- XIRP1 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 350/499 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZC3H13 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 315/637 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM5 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCA1 | c.2979C>T p.H993= | Silent (SNP) | VAF 192/361 reads (53%) | called by muse, mutect2, varscan2
- ABCA5 | c.1098T>G p.T366= | Silent (SNP) | VAF 153/153 reads (100%) | catalogued as COSV67017549; called by muse, mutect2, varscan2
- ADAM19 | c.528C>T p.F176= | Silent (SNP) | VAF 209/445 reads (47%) | catalogued as rs199763273, COSV57428271; called by muse, mutect2, varscan2
- ANKRD62 | c.444T>C p.N148= | Silent (SNP) | VAF 86/249 reads (35%) | called by muse, mutect2, varscan2
- CTSE | c.633T>A p.A211= (on ENST00000360218; = p.A206= on NM_001910.4) | Silent (SNP) | VAF 25/702 reads (4%) | catalogued as COSV63061951; called by muse, mutect2
- ERICH3 | c.2031C>G p.T677= | Silent (SNP) | VAF 311/312 reads (100%) | called by muse, mutect2, varscan2
- FREM3 | c.1044C>T p.N348= | Silent (SNP) | VAF 170/553 reads (31%) | catalogued as rs775374923, COSV61682338; called by muse, mutect2
- FRY | c.3402C>T p.F1134= | Silent (SNP) | VAF 218/456 reads (48%) | called by muse, mutect2, varscan2
- GDPGP1 | c.460C>T p.L154= | Silent (SNP) | VAF 308/606 reads (51%) | called by muse, mutect2, varscan2
- GFOD1 | c.1101G>A p.E367= | Silent (SNP) | VAF 502/823 reads (61%) | called by muse, mutect2, varscan2
- GPR101 | c.51G>A p.T17= | Silent (SNP) | VAF 206/945 reads (22%) | called by muse, varscan2
- HELZ2 | c.4407G>A p.P1469= (on ENST00000467148 / NM_001037335.2; = p.P900= on NM_033405.3) | Silent (SNP) | VAF 179/694 reads (26%) | catalogued as rs903203958, COSV101427570; called by muse, varscan2
- IL36RN | c.36G>A p.K12= | Silent (SNP) | VAF 265/265 reads (100%) | called by muse, mutect2, varscan2
- KCNB2 | c.1512C>T p.S504= | Silent (SNP) | VAF 109/465 reads (23%) | catalogued as COSV73052845; called by muse, mutect2, varscan2
- KIF26B | c.4917C>T p.D1639= | Silent (SNP) | VAF 142/906 reads (16%) | catalogued as rs762916786; called by muse, mutect2, varscan2
- KRTAP13-2 | c.225C>T p.P75= | Silent (SNP) | VAF 140/609 reads (23%) | called by muse, mutect2, varscan2
- MROH2A | c.3999G>A p.L1333= | Silent (SNP) | VAF 272/272 reads (100%) | called by muse, mutect2, varscan2
- NRN1 | c.66G>A p.V22= | Silent (SNP) | VAF 191/511 reads (37%) | called by muse, mutect2, varscan2
- NRXN3 | c.1185C>T p.S395= (on ENST00000335750 / NM_001330195.2; = p.S22= on NM_004796.6) | Silent (SNP) | VAF 313/313 reads (100%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1687C>T p.L563= | Silent (SNP) | VAF 272/618 reads (44%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1866C>T p.I622= | Silent (SNP) | VAF 259/491 reads (53%) | catalogued as rs370339346; called by muse, mutect2, varscan2
- PLPP4 | c.426C>T p.F142= | Silent (SNP) | VAF 346/346 reads (100%) | catalogued as rs754081575; called by muse, mutect2, varscan2
- POLH | c.2121T>C p.F707= | Silent (SNP) | VAF 292/452 reads (65%) | called by muse, mutect2, varscan2
- PPFIA4 | c.228C>T p.L76= | Silent (SNP) | VAF 184/463 reads (40%) | catalogued as rs1159615463, COSV55322708; called by muse, mutect2, varscan2
- PPP1R35 | c.384G>A p.K128= | Silent (SNP) | VAF 306/622 reads (49%) | catalogued as rs1333385479; called by muse, mutect2, varscan2
- RNF123 | c.3159G>A p.Q1053= | Silent (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- RPS3A | c.615T>C p.Y205= | Silent (SNP) | VAF 98/280 reads (35%) | catalogued as rs1320534664; called by muse, mutect2, varscan2
- SPATA20 | c.549C>T p.F183= (on ENST00000356488 / NM_001258372.1; = p.F199= on NM_022827.4) | Silent (SNP) | VAF 484/486 reads (100%) | called by muse, mutect2, varscan2
- TAS2R60 | c.360G>A p.V120= | Silent (SNP) | VAF 253/558 reads (45%) | catalogued as COSV60330157; called by muse, mutect2, varscan2
- TEX14 | c.2181G>A p.T727= (on ENST00000240361 / NM_001201457.2; = p.T721= on NM_031272.5) | Silent (SNP) | VAF 410/410 reads (100%) | catalogued as rs769565715; called by muse, mutect2, varscan2
- TGFBR3 | c.1806C>A p.L602= | Silent (SNP) | VAF 108/379 reads (28%) | catalogued as COSV53026875; called by muse, mutect2, varscan2
- VPS35L | c.918C>T p.F306= | Silent (SNP) | VAF 183/399 reads (46%) | catalogued as rs755826217, COSV51991404; called by muse, mutect2, varscan2
- WNT8A | c.834C>T p.N278= | Silent (SNP) | VAF 126/444 reads (28%) | called by muse, mutect2, varscan2
- ZBTB46 | c.1713G>A p.S571= | Silent (SNP) | VAF 133/745 reads (18%) | catalogued as rs374526453; called by muse, mutect2, varscan2
- ZNF28 | c.1479A>G p.K493= | Silent (SNP) | VAF 60/465 reads (13%) | catalogued as COSV60425363; called by muse, mutect2, varscan2
- ATAD3B | c.*340G>A | 3'UTR (SNP) | VAF 440/521 reads (84%) | called by muse, mutect2, varscan2
- OBSCN | c.2653+2059G>C | Intron (SNP) | VAF 58/271 reads (21%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+2280G>A | Intron (SNP) | VAF 84/275 reads (31%) | called by muse, mutect2, varscan2
